Somatic mutation profile of tumor specimen 0DOA3V from CCDI case PBCCJV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,866 days).
Specimen 0DOA3V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 617c86f5-3fe2-4467-8d87-847b37f4abbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA29 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83a5fac-9356-46dc-847b-3cfdb6578a52

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, Intron 2, Splice Site 2, RNA 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 208/642 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSEN2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 119/599 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs63750048, CM081407; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 326/378 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP40 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 431/1019 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146978120; called by muse, mutect2, varscan2
- ATP13A4 | c.465C>G p.D155E | Missense Mutation (SNP) | VAF 377/869 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.812); catalogued as rs1210080101; called by muse, mutect2, varscan2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 363/882 reads (41%) | catalogued as COSV64873412; called by muse, mutect2, varscan2
- GIMAP1 | c.479del p.G160Afs*7 | Frame Shift Del (DEL) | VAF 116/560 reads (21%) | catalogued as COSV56190331; called by mutect2, varscan2
- MCF2 | c.1191+1G>T p.X397_splice | Splice Site (SNP) | VAF 158/755 reads (21%) | catalogued as COSV104407555; called by muse, mutect2, varscan2
- ROR2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 102/515 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1354399868, COSV65217073; called by muse, mutect2, varscan2
- SDK1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 338/814 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs1364713936, COSV67357225; called by muse, mutect2, varscan2
- XIRP2 | c.3142A>T p.I1048F (on ENST00000628543; = p.I1223F on NM_152381.6) | Missense Mutation (SNP) | VAF 170/877 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54697753; called by mutect2, varscan2
- ZNF674 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 209/795 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs781188926; called by muse, mutect2, varscan2
- APOA4 | c.48C>A p.A16= | Splice Region (SNP) | VAF 303/731 reads (41%) | called by muse, mutect2, varscan2
- CGN | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 331/744 reads (44%) | called by muse, mutect2, varscan2
- DRP2 | c.1054+1G>T p.X352_splice | Splice Site (SNP) | VAF 118/555 reads (21%) | called by muse, mutect2, varscan2
- FBP2 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 125/620 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGAP6 | c.1542C>A p.H514Q | Missense Mutation (SNP) | VAF 79/697 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PLAC8L1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 432/531 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRX | c.3127G>C p.A1043P | Missense Mutation (SNP) | VAF 219/249 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SLC10A3 | c.666C>G p.S222R | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SOX10 | c.1011_1015dup p.G339Dfs*20 | Frame Shift Ins (INS) | VAF 134/326 reads (41%) | called by mutect2, varscan2
- THRB | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 123/839 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TOPAZ1 | c.1521G>T p.W507C | Missense Mutation (SNP) | VAF 127/634 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CSF2RA | c.768C>T p.D256= | Silent (SNP) | VAF 83/252 reads (33%) | catalogued as rs764658015; called by muse, mutect2, varscan2
- KLF18 | c.649C>T p.L217= | Silent (SNP) | VAF 9/296 reads (3%) | called by muse, mutect2
- LAS1L | c.1770G>A p.E590= | Silent (SNP) | VAF 169/411 reads (41%) | called by muse, mutect2, varscan2
- MKLN1 | c.1599C>T p.L533= | Silent (SNP) | VAF 54/1488 reads (4%) | catalogued as COSV61762733; called by muse, mutect2
- TAAR1 | c.777T>C p.V259= | Silent (SNP) | VAF 304/737 reads (41%) | catalogued as COSV51587920; called by muse, mutect2, varscan2
- VPS13A | c.6273A>C p.L2091= | Silent (SNP) | VAF 133/805 reads (17%) | catalogued as rs780223086; called by muse, mutect2, varscan2
- CELF4 | c.801+14C>T | Intron (SNP) | VAF 248/617 reads (40%) | catalogued as rs763911803; called by muse, mutect2, varscan2
- GRAMD1B | c.2127+43C>T | Intron (SNP) | VAF 30/148 reads (20%) | catalogued as rs746116921; called by muse, mutect2, varscan2
- TCP10L3 | n.234G>T | RNA (SNP) | VAF 291/700 reads (42%) | called by muse, mutect2, varscan2
